CCDI case PBBZKV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Lymph nodes.
https://portal.gdc.cancer.gov/cases/530d53b2-9035-44a5-87d6-5081bb787840

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, metastatic, NOS: ICD-O-3 morphology code: 8070/6; Tissue or organ of origin: Lymph nodes of head, face and neck; Age at diagnosis: 15.2 years (5,557 days).

Biospecimens (3 samples)
- Sample 0DLZNB: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLZOJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DLZON: Tissue type: Tumor; Specimen type: Solid Tissue.
